Somatic mutation profile of tumor specimen MP2PRT-PAUXFS-TMP1-A (aliquot MP2PRT-PAUXFS-TMP1-A-1-0-D-A83P-36) from MP2PRT case MP2PRT-PAUXFS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,780 days).
Specimen MP2PRT-PAUXFS-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07c02788-a134-4b66-b8b4-f1a6b9e18852.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUXFS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUXFS-NB1-A-1-0-D-A83P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6f9f3b6-9b28-4011-9732-c028ae94448e

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 1, Splice Site 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP11A | c.573G>A p.T191= | Splice Region (SNP) | VAF 46/206 reads (22%) | catalogued as rs755176406; called by muse, mutect2, varscan2
- NPAS2 | c.2096C>T p.T699M | Missense Mutation (SNP) | VAF 87/197 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs149857680; called by muse, mutect2, varscan2
- SDC4 | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 133/262 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs202098356; called by muse, mutect2, varscan2
- SLC2A10 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 186/477 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.36); catalogued as rs770882223, COSV100826425; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TSHZ2 | c.1600G>A p.G534R | Missense Mutation (SNP) | VAF 183/390 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs930326171, COSV61587378, COSV61590906; called by muse, mutect2, varscan2
- CCDC73 | c.315+1del p.X105_splice | Splice Site (DEL) | VAF 36/93 reads (39%) | called by mutect2, pindel, varscan2
- LRRN3 | c.1368G>A p.W456* | Nonsense Mutation (SNP) | VAF 112/257 reads (44%) | called by muse, mutect2, varscan2
- OR10H1 | c.440G>T p.C147F | Missense Mutation (SNP) | VAF 198/456 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- CLEC4M | c.1194C>T p.D398= | Silent (SNP) | VAF 70/160 reads (44%) | catalogued as rs750026133, COSV50216917; called by muse, mutect2, varscan2
- F11 | c.804C>T p.R268= | Silent (SNP) | VAF 112/259 reads (43%) | catalogued as rs1295896415; called by muse, mutect2
- ORC1 | c.807G>A p.S269= | Silent (SNP) | VAF 91/191 reads (48%) | catalogued as rs769149749, COSV65363310; called by muse, mutect2, varscan2
- IGHV3-53 | chr14:106592675 ins CC | 3'Flank (INS) | VAF 28/48 reads (58%) | called by pindel, varscan2
